CGCI case BLGSP-71-17-00232 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d0c895b-6c1f-478d-a25f-6ff13a9dbe39

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 30 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 30.6 years (11,186 days); Year of diagnosis: 2014; Method of diagnosis: Core Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,259 days (3.4 years); Ann Arbor extranodal involvement: No; Max tumor bulk site: Axillary lymph nodes.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90.
- Days to follow up: 1,259 days (3.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 303 [Blood test normal range upper: 246].

Other clinical attributes
- Day 0: Weight: 66.3 kg; Height: 167.5 cm; BMI: 23.6.

Biospecimens (2 samples)
- Sample BLGSP-71-17-00232-01B: Sample type: Slides; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-17-00232-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt Lymphoma; Days from index date to tumor sample procurement: 14.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 303.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
